Somatic mutation profile of tumor specimen TCGA-QH-A6CU-01A (aliquot TCGA-QH-A6CU-01A-11D-A31L-08) from TCGA case TCGA-QH-A6CU, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 52.4 years (19,149 days).
Specimen TCGA-QH-A6CU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30e5682e-bc8b-4c6c-9b11-cbd3d0c29bf2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QH-A6CU-10A (Blood Derived Normal), aliquot TCGA-QH-A6CU-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ede95810-e0ee-4d3b-959d-6653b0ff8844

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Silent 2, Frame Shift Ins 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 24/83 reads (29%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACAN | c.5093G>A p.S1698N | Missense Mutation (SNP) | VAF 54/253 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.155); catalogued as rs375118386; called by muse, mutect2, varscan2
- ADAMTS9 | c.4646G>T p.C1549F | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99899388; called by muse, mutect2, varscan2
- AVPR1A | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 90/248 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1442129687, COSV100146849; called by muse, mutect2, varscan2
- CRISPLD2 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV99295638; called by muse, mutect2, varscan2
- FZR1 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100553589; called by muse, mutect2, varscan2
- HCFC1 | c.2266G>T p.V756F | Missense Mutation (SNP) | VAF 106/324 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV100128496, COSV60073030; called by muse, mutect2, varscan2
- IFNA21 | c.236T>A p.V79D | Missense Mutation (SNP) | VAF 67/201 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV101207422; called by muse, mutect2, varscan2
- OR14C36 | c.315dup p.V106Cfs*14 | Frame Shift Ins (INS) | VAF 16/48 reads (33%) | catalogued as rs761899382; called by mutect2, varscan2
- RREB1 | c.3707G>A p.R1236Q | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as rs374868150; called by muse, mutect2, varscan2
- SATL1 | c.754C>T p.R252* (on ENST00000395409; = p.R439* on NM_001012980.2) | Nonsense Mutation (SNP) | VAF 12/255 reads (5%) | catalogued as rs1354289510, COSV100260630, COSV60576193; called by muse, mutect2
- TCN1 | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766356612, COSV57252638; called by muse, mutect2, varscan2
- MTBP | c.2136del p.D713Ifs*22 | Frame Shift Del (DEL) | VAF 26/120 reads (22%) | called by mutect2, pindel, varscan2
- CASC3 | c.1698G>A p.P566= | Silent (SNP) | VAF 90/243 reads (37%) | catalogued as rs753482185, COSV52869208; called by muse, mutect2, varscan2
- SLC39A14 | c.786G>A p.S262= | Silent (SNP) | VAF 7/86 reads (8%) | catalogued as rs140196421, COSV51487060; called by muse, mutect2
